Surgical pathology report (de-identified scan), TCGA case TCGA-XP-A8T6, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XP-A8T6-01A (Primary Tumor).

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site: Esophagus, distal third
C15.5

QW 11/29/14

Nature of material: Esophagus

Received on:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received in formalin, product of esophagectomy and proximal partial gastrectomy, previously cut, comprising esophageal segment measuring 10.1 cm long with diameters ranging from 1 to 3.8 cm and proximal gastric segment measuring 4.5 cm and 9.3 cm long, in its lesser and greater curvatures, respectively. The proximal part is fastened by surgical thread, while the distal portion is delimited by metallic suture. In the distal esophagus, near the transition to the stomach, there is a ulcerative-vegetative, circumferential and stenosing lesion, measuring 5.5 x 4.2 cm in size, apparently without extension to the cardia. On sectioning, the tissue is whitish, hardened, permeated by blackened and friable areas, infiltrating the esophageal wall into the muscular layer. 4 fibroelastic and brownish oval structures were dissected, with diameters ranging from 0.3 to 0.6 cm from periesophagic fat. From large and small gastric curvature were dissected 10 similar structures with diameters ranging from 0.2 to 2.3 cm, with the two largest infiltrated by hardened tissue and located in the greater curvature.

MICROSCOPY

Description dispensable.

DIAGNOSTIC

Product of distal esophagectomy and proximal gastrectomy:

- Squamous cell carcinoma, moderately differentiated and ulcerated, involving the distal esophagus and measuring 5.5 cm in its greatest diameter. Proximal and distal surgical margins free of neoplasia.
- The tumor infiltrated into the muscular layer of the esophagus.
- No extension to the stomach (cardia).
- Presence of high-grade dysplasia in the adjacent esophageal mucosa.
- Presence of angiolymphatic foci.
- Infiltration of four metastatic lymph nodes from a total of 14 dissected (3 periesophageal and 11 pericardial).
- Pathological staging (TNM): pT2, pN1b, pMx.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Criteria	Raw 11/8/13	Yes	No
Discrepancy			
TPAX Discrepancy			
Tumor Multiplicity History			
Site / Site Discrepancy Primary Site			

Source: NCI Genomic Data Commons file ba6b1376-2aac-44d5-9477-922935974448 (TCGA-XP-A8T6.3C4F0AE9-85BA-4BC9-A74F-C9F0ACD2C638.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).